Somatic mutation profile of tumor specimen TCGA-R6-A6DN-01B (aliquot TCGA-R6-A6DN-01B-11D-A31U-09) from TCGA case TCGA-R6-A6DN, project TCGA-ESCA (Esophageal Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Middle third of esophagus; Tumor grade: G3; Age at diagnosis: 58.2 years (21,259 days).
Specimen TCGA-R6-A6DN-01B: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 83307c49-e476-46c1-994d-2625fc375628.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-R6-A6DN-10A (Blood Derived Normal), aliquot TCGA-R6-A6DN-10A-01D-A31U-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/8aec9897-96a5-4864-8e57-23c37f02fbd3

The open-access MAF lists 97 somatic variants for this specimen: 70 protein-altering or splice-affecting, 25 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 59, Silent 25, Nonsense Mutation 5, Frame Shift Ins 2, Splice Site 1, Nonstop Mutation 1, Frame Shift Del 1, 3'UTR 1, RNA 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.742C>T p.R248W | Missense Mutation (SNP) | VAF 40/45 reads (89%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs121912651, CM010465, CM900211, COSV52662035, COSV52797251, COSV53097881; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ABTB1 | c.1009A>G p.M337V (on ENST00000232744 / NM_172027.3; = p.M195V on NM_032548.3) | Missense Mutation (SNP) | VAF 3/10 reads (30%) | SIFT tolerated (0.69); PolyPhen benign (0); catalogued as rs1312015984; called by muse, mutect2
- ACSF2 | c.374A>G p.D125G | Missense Mutation (SNP) | VAF 28/32 reads (88%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51973889; called by muse, mutect2, varscan2
- ALX1 | c.743G>A p.C248Y | Missense Mutation (SNP) | VAF 11/48 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.852); catalogued as rs765645567; called by muse, mutect2, varscan2
- ASB5 | c.863C>A p.A288D | Missense Mutation (SNP) | VAF 6/14 reads (43%) | SIFT deleterious (0.03); PolyPhen benign (0.244); catalogued as COSV56672130; called by muse, mutect2, varscan2
- BBS2 | c.1700T>C p.I567T | Missense Mutation (SNP) | VAF 25/32 reads (78%) | SIFT deleterious (0); PolyPhen possibly damaging (0.571); catalogued as rs756945477; called by muse, mutect2, varscan2
- BCAR1 | c.2117G>A p.R706Q | Missense Mutation (SNP) | VAF 8/28 reads (29%) | SIFT tolerated (0.26); PolyPhen probably damaging (0.986); catalogued as rs376571253; called by muse, mutect2, varscan2
- C12orf40 | c.571C>T p.R191C | Missense Mutation (SNP) | VAF 6/40 reads (15%) | SIFT tolerated (0.09); PolyPhen benign (0.001); catalogued as rs568770394, COSV61135976; called by mutect2, varscan2
- CARD10 | c.755G>A p.R252Q | Missense Mutation (SNP) | VAF 4/11 reads (36%) | SIFT deleterious (0.02); PolyPhen benign (0.097); catalogued as rs1177053530; called by muse, mutect2, varscan2
- CELSR1 | c.4130G>A p.R1377H | Missense Mutation (SNP) | VAF 25/44 reads (57%) | SIFT tolerated (0.56); PolyPhen benign (0.014); catalogued as rs1289165496; called by muse, mutect2, varscan2
- CSF2RB | c.2539G>T p.E847* | Nonsense Mutation (SNP) | VAF 3/50 reads (6%) | catalogued as COSV99453982; called by muse, mutect2
- CUX1 | c.1316G>A p.G439E | Missense Mutation (SNP) | VAF 6/46 reads (13%) | SIFT tolerated (0.44); PolyPhen benign (0.056); catalogued as COSV52896430; called by mutect2, varscan2
- DCBLD2 | c.101G>A p.R34H | Missense Mutation (SNP) | VAF 6/16 reads (38%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0); catalogued as rs1175991538; called by muse, mutect2, varscan2
- DNAH6 | c.1744A>C p.S582R | Missense Mutation (SNP) | VAF 31/87 reads (36%) | SIFT deleterious (0.04); PolyPhen benign (0.031); catalogued as COSV52887588; called by muse, mutect2, varscan2
- GATA3 | c.168A>C p.Q56H | Missense Mutation (SNP) | VAF 59/92 reads (64%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.956); catalogued as rs1268005860; called by muse, mutect2, varscan2
- GRIA1 | c.2721A>C p.*907Yext*52 | Nonstop Mutation (SNP) | VAF 7/19 reads (37%) | catalogued as COSV53588898; called by muse, mutect2, varscan2
- HECW1 | c.4730G>A p.R1577Q | Missense Mutation (SNP) | VAF 14/26 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1434525710, COSV67842542; called by muse, mutect2, varscan2
- ICAM1 | c.119G>A p.R40Q | Missense Mutation (SNP) | VAF 12/45 reads (27%) | SIFT tolerated (0.32); PolyPhen benign (0.068); catalogued as rs756786973, COSV53424881; called by muse, mutect2, varscan2
- IMPG1 | c.2123C>T p.A708V | Missense Mutation (SNP) | VAF 8/22 reads (36%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.998); catalogued as rs765332581, COSV63113102; called by muse, mutect2, varscan2
- KCNB1 | c.841G>A p.E281K | Missense Mutation (SNP) | VAF 7/37 reads (19%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.49); catalogued as COSV65567935; called by muse, mutect2, varscan2
- KDM2A | c.1292G>A p.R431Q | Missense Mutation (SNP) | VAF 25/28 reads (89%) | SIFT tolerated (0.54); PolyPhen benign (0.441); catalogued as rs200011930; called by muse, mutect2, varscan2
- LRP1B | c.12044G>T p.G4015V | Missense Mutation (SNP) | VAF 12/53 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV101259159, COSV67227651; called by muse, mutect2, varscan2
- MSC | c.443C>T p.T148M | Missense Mutation (SNP) | VAF 10/37 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV57697357; called by muse, mutect2, varscan2
- MYO18B | c.2911G>A p.A971T | Missense Mutation (SNP) | VAF 31/43 reads (72%) | SIFT tolerated (0.41); PolyPhen benign (0.006); catalogued as rs780465835; called by muse, mutect2, varscan2
- PAX1 | c.1153G>A p.G385S | Missense Mutation (SNP) | VAF 11/25 reads (44%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.019); catalogued as rs747116290, COSV101270209; called by muse, varscan2
- PCDHGA5 | c.1036G>A p.E346K | Missense Mutation (SNP) | VAF 18/38 reads (47%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.98); catalogued as rs764735476, COSV53983371, COSV54040391; called by muse, mutect2, varscan2
- PPARGC1A | c.487G>A p.G163S | Missense Mutation (SNP) | VAF 49/59 reads (83%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs1166778125; called by muse, mutect2, varscan2
- RFPL3 | c.124G>A p.V42I (on ENST00000249007 / NM_001098535.1; = p.V13I on NM_006604.2) | Missense Mutation (SNP) | VAF 33/50 reads (66%) | SIFT tolerated (0.68); PolyPhen benign (0.069); catalogued as rs770073454, COSV50748548; called by muse, mutect2, varscan2
- RPS6KA6 | c.1907G>A p.R636H | Missense Mutation (SNP) | VAF 19/50 reads (38%) | SIFT deleterious (0.01); PolyPhen benign (0.125); catalogued as rs750299675, COSV53117701; called by muse, mutect2, varscan2
- RTL3 | c.991C>A p.Q331K | Missense Mutation (SNP) | VAF 26/34 reads (76%) | SIFT tolerated (0.24); PolyPhen benign (0.003); catalogued as COSV58183583; called by muse, mutect2, varscan2
- SHMT1 | c.253G>A p.G85R | Missense Mutation (SNP) | VAF 12/27 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as rs373431106; called by muse, mutect2, varscan2
- SLC17A4 | c.64G>A p.V22M | Missense Mutation (SNP) | VAF 24/38 reads (63%) | SIFT tolerated (0.73); PolyPhen benign (0.015); catalogued as rs576691816; called by muse, mutect2, varscan2
- SLC6A1 | c.1723G>A p.E575K | Missense Mutation (SNP) | VAF 19/22 reads (86%) | SIFT tolerated (0.62); PolyPhen benign (0.001); catalogued as COSV55114504; called by muse, mutect2, varscan2
- TRIM50 | c.1219G>A p.V407M | Missense Mutation (SNP) | VAF 8/25 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.873); catalogued as rs372424421; called by muse, mutect2, varscan2
- ZFR2 | c.2365G>A p.V789M | Missense Mutation (SNP) | VAF 18/58 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.893); catalogued as rs751131550, COSV99507995; called by muse, mutect2, varscan2
- ZNF99 | c.1235T>G p.L412R | Missense Mutation (SNP) | VAF 17/51 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV68055042; called by muse, mutect2, varscan2
- ABCB11 | c.2263A>G p.M755V | Missense Mutation (SNP) | VAF 13/21 reads (62%) | SIFT tolerated (0.38); PolyPhen benign (0.111); called by muse, mutect2, varscan2
- AMPH | c.17C>T p.T6M | Missense Mutation (SNP) | VAF 28/40 reads (70%) | SIFT deleterious (0); PolyPhen possibly damaging (0.877); called by muse, mutect2, varscan2
- CFTR | c.2570del p.K857Rfs*3 | Frame Shift Del (DEL) | VAF 17/104 reads (16%) | called by mutect2, pindel, varscan2
- CNTN1 | c.1777T>C p.S593P | Missense Mutation (SNP) | VAF 4/48 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.944); called by muse, mutect2
- DNAJC1 | c.82C>G p.R28G | Missense Mutation (SNP) | VAF 9/24 reads (38%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0.003); called by muse, mutect2
- ENTPD5 | c.1216A>G p.N406D | Missense Mutation (SNP) | VAF 7/22 reads (32%) | SIFT tolerated (0.44); PolyPhen probably damaging (0.964); called by muse, mutect2, varscan2
- EPHA7 | c.2371T>C p.Y791H | Missense Mutation (SNP) | VAF 13/16 reads (81%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- FCGR2B | c.391+2T>C p.X131_splice | Splice Site (SNP) | VAF 55/142 reads (39%) | called by muse, mutect2, varscan2
- FRMD4A | c.241G>A p.V81I | Missense Mutation (SNP) | VAF 5/32 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by mutect2, varscan2
- FRMD4B | c.1660G>T p.E554* | Nonsense Mutation (SNP) | VAF 8/43 reads (19%) | called by muse, mutect2, varscan2
- IGHV3-23 | c.245C>A p.S82Y | Missense Mutation (SNP) | VAF 69/226 reads (31%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.654); called by muse, mutect2, varscan2
- JDP2 | c.13C>T p.Q5* | Nonsense Mutation (SNP) | VAF 17/68 reads (25%) | called by muse, mutect2, varscan2
- LHCGR | c.703C>T p.Q235* | Nonsense Mutation (SNP) | VAF 13/26 reads (50%) | called by muse, mutect2, varscan2
- LRP1B | c.12043G>A p.G4015S | Missense Mutation (SNP) | VAF 13/55 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- MBOAT7 | c.336G>A p.L112= | Splice Region (SNP) | VAF 8/23 reads (35%) | called by muse, mutect2, varscan2
- MYO7B | c.2040G>A p.M680I | Missense Mutation (SNP) | VAF 5/38 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.91); called by muse, mutect2
- NLGN1 | c.477T>A p.Y159* | Nonsense Mutation (SNP) | VAF 5/13 reads (38%) | called by muse, mutect2, varscan2
- PLSCR5 | c.704A>G p.N235S | Missense Mutation (SNP) | VAF 38/49 reads (78%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.893); called by muse, mutect2, varscan2
- POLN | c.145A>T p.I49L | Missense Mutation (SNP) | VAF 16/21 reads (76%) | SIFT tolerated (0.44); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- POLR3D | c.526dup p.M176Nfs*15 | Frame Shift Ins (INS) | VAF 5/25 reads (20%) | called by mutect2, pindel, varscan2
- PSG7 | c.1150A>G p.I384V | Missense Mutation (SNP) | VAF 9/197 reads (5%) | SIFT tolerated (1); PolyPhen benign (0.015); called by muse, mutect2
- PTPRZ1 | c.5463A>C p.E1821D | Missense Mutation (SNP) | VAF 47/64 reads (73%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.908); called by muse, mutect2, varscan2
- RETREG2 | c.301C>T p.L101F | Missense Mutation (SNP) | VAF 10/38 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- SCGB3A2 | c.271_278dup p.*94Tfs*42 | Frame Shift Ins (INS) | VAF 8/38 reads (21%) | called by mutect2, varscan2
- SEPTIN1 | c.730C>T p.H244Y (on ENST00000321367; = p.H197Y on NM_052838.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 8/15 reads (53%) | SIFT deleterious (0); PolyPhen benign (0.184); called by muse, mutect2, varscan2
- SNAP91 | c.2425C>T p.P809S | Missense Mutation (SNP) | VAF 10/16 reads (63%) | SIFT tolerated (0.33); PolyPhen possibly damaging (0.66); called by muse, mutect2, varscan2
- TERF2 | c.1321C>T p.P441S | Missense Mutation (SNP) | VAF 32/61 reads (52%) | SIFT tolerated (0.65); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- TGM7 | c.1282G>A p.E428K | Missense Mutation (SNP) | VAF 9/34 reads (26%) | SIFT tolerated (0.37); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- TNFRSF25 | c.1031C>T p.A344V | Missense Mutation (SNP) | VAF 11/28 reads (39%) | SIFT tolerated (0.49); PolyPhen possibly damaging (0.525); called by muse, mutect2, varscan2
- TRPC6 | c.73C>T p.R25C | Missense Mutation (SNP) | VAF 9/18 reads (50%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.973); called by muse, mutect2, varscan2
- TTN | c.52282G>T p.A17428S (on ENST00000591111; = p.A10004S on NM_003319.4) | Missense Mutation (SNP) | VAF 18/66 reads (27%) | PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- TXNRD1 | c.633T>A p.N211K (on ENST00000525566 / NM_001093771.3; = p.N113K on NM_003330.4) | Missense Mutation (SNP) | VAF 5/25 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- VIM | c.864A>C p.E288D | Missense Mutation (SNP) | VAF 16/26 reads (62%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.533); called by muse, mutect2, varscan2
- XKR3 | c.1316A>G p.N439S | Missense Mutation (SNP) | VAF 7/18 reads (39%) | SIFT tolerated, low confidence (0.36); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- ACHE | c.1101G>A p.S367= | Silent (SNP) | VAF 7/46 reads (15%) | catalogued as rs761981699; called by muse, mutect2, varscan2
- AMY2A | c.153A>T p.G51= | Silent (SNP) | VAF 53/79 reads (67%) | called by muse, mutect2, varscan2
- BORCS8-MEF2B | c.51G>A p.T17= | Silent (SNP) | VAF 12/28 reads (43%) | catalogued as rs755911329, COSV50761526; called by muse, mutect2, varscan2
- BRCA1 | c.4131C>T p.S1377= | Silent (SNP) | VAF 9/38 reads (24%) | catalogued as rs80356871, COSV100524139; ClinVar: likely benign; called by muse, mutect2, varscan2
- CABP1 | c.945C>T p.D315= (on ENST00000316803 / NM_001033677.1; = p.D112= on NM_004276.5) | Silent (SNP) | VAF 22/30 reads (73%) | called by muse, mutect2, varscan2
- CCR6 | c.387T>C p.F129= | Silent (SNP) | VAF 3/8 reads (38%) | called by muse, mutect2
- CNTNAP4 | c.3414C>A p.V1138= | Silent (SNP) | VAF 8/35 reads (23%) | catalogued as COSV100269963; called by muse, mutect2, varscan2
- DENND2B | c.819C>T p.G273= | Silent (SNP) | VAF 25/31 reads (81%) | called by muse, mutect2, varscan2
- DMPK | c.1554G>A p.R518= | Silent (SNP) | VAF 4/21 reads (19%) | catalogued as rs1333628902; called by muse, mutect2, varscan2
- DYNC2H1 | c.5733G>A p.T1911= | Silent (SNP) | VAF 23/36 reads (64%) | catalogued as rs950887766; called by muse, mutect2, varscan2
- EPHA7 | c.2370C>T p.V790= | Silent (SNP) | VAF 13/16 reads (81%) | catalogued as COSV100994386; called by muse, mutect2, varscan2
- GDF2 | c.309G>A p.T103= | Silent (SNP) | VAF 10/24 reads (42%) | catalogued as rs782687950; called by muse, mutect2, varscan2
- H3C3 | c.156C>T p.I52= | Silent (SNP) | VAF 41/73 reads (56%) | catalogued as rs1045347939, COSV63551120; called by muse, mutect2, varscan2
- HCN1 | c.2361C>T p.S787= | Silent (SNP) | VAF 6/20 reads (30%) | catalogued as rs758609806, COSV57510971; called by muse, mutect2, varscan2
- HDAC5 | c.1449G>A p.T483= | Silent (SNP) | VAF 12/25 reads (48%) | catalogued as rs371064760; called by muse, mutect2, varscan2
- MAP3K5 | c.2466C>T p.D822= | Silent (SNP) | VAF 55/91 reads (60%) | catalogued as rs1326523947; called by muse, mutect2, varscan2
- MUC16 | c.16773A>T p.G5591= | Silent (SNP) | VAF 6/31 reads (19%) | called by muse, mutect2, varscan2
- OR2L3 | c.784A>C p.R262= | Silent (SNP) | VAF 72/83 reads (87%) | called by muse, mutect2, varscan2
- PARD6G | c.846G>A p.P282= | Silent (SNP) | VAF 5/11 reads (45%) | catalogued as rs761643537, COSV100783298; called by muse, mutect2
- SH3RF2 | c.1224G>A p.R408= | Silent (SNP) | VAF 10/36 reads (28%) | catalogued as rs375118719; called by muse, mutect2, varscan2
- SIDT1 | c.1629T>C p.G543= | Silent (SNP) | VAF 16/96 reads (17%) | called by muse, mutect2, varscan2
- SLC30A5 | c.108A>G p.L36= | Silent (SNP) | VAF 8/46 reads (17%) | catalogued as rs1456876924; called by muse, mutect2, varscan2
- SMARCAL1 | c.822C>G p.T274= | Silent (SNP) | VAF 19/62 reads (31%) | called by muse, mutect2, varscan2
- SRMS | c.1341C>G p.R447= | Silent (SNP) | VAF 15/30 reads (50%) | called by muse, mutect2, varscan2
- ZXDC | c.1702C>T p.L568= | Silent (SNP) | VAF 5/32 reads (16%) | called by muse, mutect2, varscan2
- ANKRD13D | c.*478G>A | 3'UTR (SNP) | VAF 48/54 reads (89%) | catalogued as rs370874560, COSV100398659; called by muse, mutect2, varscan2
- SNORD115-4 | n.41G>T | RNA (SNP) | VAF 53/82 reads (65%) | called by muse, mutect2, varscan2
